Somatic mutation profile of tumor specimen TCGA-AA-3986-01A (aliquot TCGA-AA-3986-01A-02W-0995-10) from TCGA case TCGA-AA-3986, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 73.8 years (26,967 days).
Specimen TCGA-AA-3986-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 393cdeb6-5b59-4e11-addc-01f2a9e22038.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-3986-10A (Blood Derived Normal), aliquot TCGA-AA-3986-10A-01W-0999-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7af81a9d-8ef8-4981-ad46-5713ca401d69

The open-access MAF lists 93 somatic variants for this specimen: 65 protein-altering or splice-affecting, 27 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 58, Silent 27, Nonsense Mutation 6, Intron 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 35/183 reads (19%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.844); catalogued as rs121913527, COSV55501778, COSV55541748, COSV55727828; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- SCN5A | c.4931G>A p.R1644H (on ENST00000333535 / NM_198056.3; = p.R1643H on NM_000335.5) | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as rs28937316, CM951143, COSV61120013; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- AKNA | c.1541C>T p.P514L | Missense Mutation (SNP) | VAF 51/175 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.537); catalogued as rs368698649, COSV56311502, COSV99800701; called by muse, mutect2, varscan2
- ANKRD6 | c.1435C>T p.R479C | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs780403490, COSV60229575; called by muse, mutect2, varscan2
- AP002512.3 | c.1046C>T p.T349M | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.342); catalogued as rs558210028, COSV54405409; called by mutect2, varscan2
- APCDD1L | c.1315G>A p.D439N | Missense Mutation (SNP) | VAF 75/385 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.243); catalogued as COSV64486517; called by muse, mutect2, varscan2
- ARHGEF1 | c.409C>T p.R137W | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as rs1555846487, COSV100528981; called by muse, mutect2, varscan2
- CADM3 | c.67G>A p.G23R | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.16); PolyPhen benign (0.114); catalogued as rs1406726592, COSV63686458; called by muse, mutect2, varscan2
- CLCN2 | c.2545A>G p.K849E | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as COSV99658541; called by muse, mutect2, varscan2
- COL6A6 | c.6437G>A p.R2146Q | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.99); catalogued as rs763604735, COSV100650216, COSV62030711; called by muse, mutect2, varscan2
- CYP1A1 | c.401G>A p.R134H | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.6); PolyPhen probably damaging (0.947); catalogued as rs367709511, COSV65696821; called by muse, mutect2, varscan2
- CYP2A7 | c.312A>C p.Q104H | Missense Mutation (SNP) | VAF 26/228 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.132); catalogued as COSV52503686; called by muse, mutect2, varscan2
- DAPK1 | c.92G>A p.R31H | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.502); catalogued as rs777469310, COSV63787212; called by muse, mutect2, varscan2
- DCAF12L1 | c.32G>A p.R11Q | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.778); catalogued as COSV64422256; called by muse, mutect2, varscan2
- DEFB116 | c.53C>A p.A18D | Missense Mutation (SNP) | VAF 18/546 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.143); catalogued as COSV101269229, COSV68722380; called by muse, mutect2
- DLC1 | c.1913G>T p.G638V (on ENST00000276297 / NM_001348081.2; = p.G201V on NM_006094.5) | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as COSV52314441, COSV99362876; called by muse, mutect2, varscan2
- DNMT3B | c.1138C>T p.R380* | Nonsense Mutation (SNP) | VAF 21/44 reads (48%) | catalogued as rs376213530; called by muse, varscan2
- DOCK10 | c.4979G>A p.R1660H | Missense Mutation (SNP) | VAF 48/147 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as rs1305763186, COSV51420167; called by muse, mutect2, varscan2
- DTX4 | c.1711G>A p.V571I | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs376862310; called by muse, mutect2, varscan2
- EML2 | c.419G>A p.R140H | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.999); catalogued as COSV55601847; called by muse, mutect2, varscan2
- EZH1 | c.1582G>T p.D528Y | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.078); catalogued as COSV101331360; called by muse, mutect2, varscan2
- FLG2 | c.748G>T p.E250* | Nonsense Mutation (SNP) | VAF 28/109 reads (26%) | catalogued as COSV101165703, COSV101165835; called by muse, mutect2, varscan2
- GFAP | c.689A>G p.D230G | Missense Mutation (SNP) | VAF 13/230 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99493274; called by muse, mutect2
- HECW2 | c.121A>G p.M41V | Missense Mutation (SNP) | VAF 71/224 reads (32%) | SIFT tolerated, low confidence (0.93); PolyPhen benign (0); catalogued as rs1171191009, COSV99647049; called by muse, mutect2, varscan2
- HELZ | c.3961C>T p.R1321C | Missense Mutation (SNP) | VAF 88/401 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs777241915, COSV62379647; called by muse, mutect2, varscan2
- HSPA6 | c.1588G>T p.E530* | Nonsense Mutation (SNP) | VAF 4/19 reads (21%) | catalogued as COSV100554125, COSV59061401; called by muse, mutect2, varscan2
- HTR2C | c.1001C>A p.S334Y | Missense Mutation (SNP) | VAF 114/217 reads (53%) | SIFT tolerated (1); PolyPhen probably damaging (0.977); catalogued as COSV99349216; called by muse, mutect2, varscan2
- IL24 | c.278A>T p.Q93L | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.069); catalogued as COSV54321116; called by muse, mutect2, varscan2
- KIF1A | c.1238G>A p.R413H | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.859); catalogued as rs771678168, COSV57493219; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LDHAL6A | c.134G>A p.S45N | Missense Mutation (SNP) | VAF 91/392 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.234); catalogued as COSV55008416; called by muse, mutect2, varscan2
- LOXL2 | c.211C>T p.R71W | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs763353774, COSV66690379; called by muse, mutect2, varscan2
- LSAMP | c.200G>A p.R67H | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs577289191, COSV61277398; called by muse, mutect2, varscan2
- LUZP4 | c.428C>T p.P143L | Missense Mutation (SNP) | VAF 22/36 reads (61%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs782336423, COSV64219327; called by muse, mutect2, varscan2
- MAP1B | c.4625C>T p.T1542M | Missense Mutation (SNP) | VAF 23/103 reads (22%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.998); catalogued as rs753038766, COSV57102145; called by muse, mutect2, varscan2
- MAP2K4 | c.817G>T p.E273* | Nonsense Mutation (SNP) | VAF 14/90 reads (16%) | catalogued as COSV100796243, COSV62256968; called by muse, mutect2, varscan2
- MED12L | c.3556C>A p.L1186I | Missense Mutation (SNP) | VAF 57/208 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV99852942; called by muse, mutect2, varscan2
- MRGPRX3 | c.109G>A p.V37I | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs758693095, COSV66934667; called by muse, mutect2, varscan2
- MUC16 | c.2593G>T p.E865* | Nonsense Mutation (SNP) | VAF 192/794 reads (24%) | catalogued as COSV67463989; called by muse, mutect2, varscan2
- MYBPC3 | c.845G>A p.R282Q | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.006); catalogued as rs761520688, COSV99920327; ClinVar: uncertain significance; called by muse, varscan2
- NCAPD3 | c.3644A>G p.N1215S | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV101592166; called by muse, mutect2
- NCR1 | c.41G>A p.C14Y | Missense Mutation (SNP) | VAF 73/264 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as rs769495093, COSV52557571; called by muse, mutect2, varscan2
- OAS3 | c.2900C>T p.P967L | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1371871682, COSV99966261; called by muse, mutect2, varscan2
- PADI6 | c.1339G>A p.A447T | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as rs768078844, COSV100639934, COSV99069254; called by muse, mutect2, varscan2
- PATJ | c.4184A>G p.E1395G | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.341); catalogued as COSV100219600; called by muse, mutect2
- POLR2B | c.1340C>T p.S447F | Missense Mutation (SNP) | VAF 32/150 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100108051; called by muse, mutect2, varscan2
- PTN | c.160G>T p.V54L | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.825); catalogued as COSV61963477; called by muse, mutect2, varscan2
- RALGAPA1 | c.1384C>T p.L462F | Missense Mutation (SNP) | VAF 21/107 reads (20%) | SIFT tolerated (0.7); PolyPhen benign (0.009); catalogued as COSV51889678; called by muse, mutect2, varscan2
- RGS20 | c.538C>T p.R180W (on ENST00000297313 / NM_170587.4; = p.R33W on NM_003702.4) | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs200019464, COSV52019751; called by muse, mutect2
- RIMKLB | c.291G>T p.K97N | Missense Mutation (SNP) | VAF 6/127 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.013); catalogued as COSV100223876; called by muse, mutect2
- SACS | c.7973C>A p.A2658D | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101207409; called by muse, mutect2, varscan2
- SELENOM | c.260G>A p.R87H | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as COSV60774776; called by muse, mutect2, varscan2
- SMOC2 | c.1150A>C p.K384Q (on ENST00000356284 / NM_001166412.2; = p.K395Q on NM_022138.3) | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV100635008; called by muse, mutect2
- SOX10 | c.368C>T p.A123V | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1387386886, COSV61005761; called by muse, mutect2, varscan2
- SRRT | c.1390C>T p.R464C | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV53822489, COSV99574052; called by muse, mutect2, varscan2
- TESK2 | c.685C>T p.R229* | Nonsense Mutation (SNP) | VAF 8/27 reads (30%) | catalogued as rs375688752; called by muse, mutect2, varscan2
- TFAP2D | c.523G>T p.A175S | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as COSV99145909; called by muse, mutect2, varscan2
- TGM4 | c.1830G>T p.K610N | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.098); catalogued as COSV99942295; called by muse, mutect2, varscan2
- TIGD3 | c.1372T>C p.F458L | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV52890468; called by muse, mutect2
- TRPM6 | c.2381G>A p.S794N | Missense Mutation (SNP) | VAF 46/169 reads (27%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as COSV100666273; called by muse, mutect2, varscan2
- TSHZ3 | c.1618G>A p.G540S | Missense Mutation (SNP) | VAF 24/282 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.248); catalogued as rs1356367288, COSV99551466; called by muse, mutect2
- TTLL8 | c.696C>A p.S232R | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.276); catalogued as rs763006164, COSV99838300; called by muse, mutect2, varscan2
- TTN | c.91039G>A p.V30347M (on ENST00000591111; = p.V22923M on NM_003319.4) | Missense Mutation (SNP) | VAF 18/84 reads (21%) | PolyPhen possibly damaging (0.695); catalogued as rs756469423, COSV59877746; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.36040G>A p.E12014K (on ENST00000591111; = p.E4590K on NM_003319.4) | Missense Mutation (SNP) | VAF 6/15 reads (40%) | PolyPhen benign (0.127); catalogued as rs727504198, COSV59938831; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ZYG11B | c.446C>T p.S149F | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (0.69); PolyPhen possibly damaging (0.509); catalogued as COSV53756391; called by muse, mutect2, varscan2
- PIMREG | c.601_602del p.S201* | Frame Shift Del (DEL) | VAF 21/102 reads (21%) | called by mutect2, pindel, varscan2
- ABI3BP | c.2862G>A p.E954= | Silent (SNP) | VAF 34/151 reads (23%) | catalogued as COSV52543812; called by muse, mutect2, varscan2
- AKAP13 | c.6714G>C p.V2238= (on ENST00000394518 / NM_007200.5; = p.V2242= on NM_006738.6) | Silent (SNP) | VAF 42/128 reads (33%) | catalogued as COSV100773729; called by muse, mutect2, varscan2
- ANKEF1 | c.1887C>T p.D629= | Silent (SNP) | VAF 14/61 reads (23%) | catalogued as rs370547870; called by muse, mutect2, varscan2
- ARRDC2 | c.1152G>A p.P384= | Silent (SNP) | VAF 4/15 reads (27%) | catalogued as rs774749762, COSV55845399; called by muse, mutect2
- BNC2 | c.1164C>A p.T388= | Silent (SNP) | VAF 9/26 reads (35%) | catalogued as COSV66152236; called by muse, mutect2, varscan2
- C11orf71 | c.96G>A p.A32= | Silent (SNP) | VAF 10/52 reads (19%) | catalogued as rs1156539042, COSV57784653; called by muse, mutect2, varscan2
- CACNA1A | c.3369C>T p.A1123= | Silent (SNP) | VAF 59/235 reads (25%) | catalogued as rs372364153; ClinVar: likely benign; called by muse, mutect2, varscan2
- CARD11 | c.1875C>T p.S625= | Silent (SNP) | VAF 9/62 reads (15%) | catalogued as rs138416850, COSV62756066; called by muse, mutect2, varscan2
- CECR2 | c.3363G>A p.P1121= (on ENST00000342247 / NM_001290047.2; = p.P937= on NM_001290046.1) | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as rs960677521, COSV52843611; called by muse, mutect2, varscan2
- CERS3 | c.1053G>A p.E351= | Silent (SNP) | VAF 122/478 reads (26%) | catalogued as COSV52571508, COSV99432491; called by muse, mutect2, varscan2
- DCX | c.1008G>A p.T336= (on ENST00000636035 / NM_001195553.2; = p.T331= on NM_000555.3) | Silent (SNP) | VAF 217/426 reads (51%) | catalogued as rs775046398, COSV57567784; called by muse, mutect2, varscan2
- HECTD4 | c.6129C>A p.S2043= | Silent (SNP) | VAF 98/330 reads (30%) | catalogued as COSV66395816; called by muse, varscan2
- ITGAX | c.1413C>T p.G471= | Silent (SNP) | VAF 4/45 reads (9%) | called by muse, mutect2
- KIF26B | c.1227C>T p.S409= | Silent (SNP) | VAF 34/177 reads (19%) | catalogued as rs372159973; called by muse, mutect2, varscan2
- LRFN2 | c.1635G>A p.T545= | Silent (SNP) | VAF 41/161 reads (25%) | catalogued as rs760261154, COSV57831075; called by muse, mutect2, varscan2
- LRFN2 | c.864G>A p.P288= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as rs762359520, COSV100599532; called by muse, varscan2
- MITF | c.1332G>A p.T444= (on ENST00000448226 / NM_006722.3; = p.T344= on NM_000248.4) | Silent (SNP) | VAF 20/76 reads (26%) | catalogued as rs774944729, COSV58833586; called by muse, mutect2, varscan2
- MRPS16 | c.237C>T p.C79= | Silent (SNP) | VAF 18/61 reads (30%) | catalogued as rs1293618271, COSV60285174; called by muse, mutect2, varscan2
- MTUS2 | c.1185C>T p.T395= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as rs765389051, COSV70925831; called by muse, mutect2, varscan2
- ORM2 | c.369G>A p.R123= | Silent (SNP) | VAF 44/159 reads (28%) | catalogued as rs1384357022, COSV56338616; called by muse, mutect2, varscan2
- PDHB | c.978T>C p.T326= | Silent (SNP) | VAF 35/130 reads (27%) | catalogued as COSV100240142; called by muse, mutect2, varscan2
- PIP4K2B | c.858C>T p.H286= | Silent (SNP) | VAF 9/47 reads (19%) | catalogued as rs767674989; called by muse, mutect2, varscan2
- PTX4 | c.1104G>A p.T368= (on ENST00000447419 / NM_001328608.2; = p.T363= on NM_001013658.1) | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as rs61729687, COSV53518138; called by muse, varscan2
- SLC25A3 | c.987G>A p.Q329= (on ENST00000228318 / NM_005888.3; = p.Q328= on NM_002635.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 68/285 reads (24%) | catalogued as COSV51846544; called by muse, mutect2, varscan2
- SLC6A4 | c.1497C>T p.P499= | Silent (SNP) | VAF 13/45 reads (29%) | catalogued as rs777581886, COSV55568416; called by muse, mutect2, varscan2
- ST8SIA5 | c.765C>T p.T255= | Silent (SNP) | VAF 38/105 reads (36%) | catalogued as rs773311529, COSV59333014; called by muse, mutect2, varscan2
- TWIST1 | c.375C>T p.N125= | Silent (SNP) | VAF 7/35 reads (20%) | catalogued as rs773150642, COSV99643068; called by muse, mutect2, varscan2
- ERBB4 | c.1872-122G>A | Intron (SNP) | VAF 5/25 reads (20%) | catalogued as COSV53514666, COSV99622710; called by muse, mutect2
